Somatic mutation profile of tumor specimen C3N-02087-01 (aliquot CPT0118200009) from CPTAC case C3N-02087, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.4 years (22,433 days).
Specimen C3N-02087-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acd49e6b-951f-4cae-8ec8-d69823294f0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02087-31 (Blood Derived Normal), aliquot CPT0119450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6152df76-6b63-4ce7-b0aa-9ce873992195

The open-access MAF lists 62 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Frame Shift Del 3, Intron 3, Nonsense Mutation 2, 3'UTR 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 34/263 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EXOC2 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1561908008, COSV57867863; called by muse, mutect2, varscan2
- HIVEP3 | c.5681C>T p.S1894F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs758530264; called by muse, mutect2
- IRAK3 | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs762288493, COSV99706571; called by muse, mutect2
- ISG20L2 | c.176C>A p.S59* | Nonsense Mutation (SNP) | VAF 31/225 reads (14%) | catalogued as COSV57459422; called by muse, mutect2, varscan2
- KMT2B | c.5536C>T p.R1846W | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1353394278; called by muse, mutect2
- MAPK8 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64408314; called by muse, mutect2
- SIKE1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs780432009; called by muse, mutect2
- SLC35G1 | c.488C>A p.T163K (on ENST00000427197 / NM_001134658.3; = p.T162K on NM_153226.4) | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV65055405; called by muse, mutect2
- SVEP1 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1438758569; called by muse, mutect2
- TANC1 | c.4082A>G p.K1361R | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1224181417; called by muse, mutect2
- TMCO4 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs754788119; called by muse, mutect2, varscan2
- XIRP1 | c.4916C>T p.S1639L | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs1366426163; called by muse, mutect2
- ZNF335 | c.1268C>A p.A423E | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1277890632; called by muse, mutect2
- ADRA1A | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- C4B | c.3311C>G p.S1104C | Missense Mutation (SNP) | VAF 59/497 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- DNAJC7 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FOXM1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.157); called by muse, mutect2
- GRK1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2
- GSC | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 36/395 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAKMIP2 | c.2371del p.T791Qfs*8 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | called by mutect2, pindel, varscan2
- KMT5B | c.1490A>G p.E497G | Missense Mutation (SNP) | VAF 23/278 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2
- LAMA1 | c.6397C>G p.Q2133E | Missense Mutation (SNP) | VAF 12/406 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- LZTR1 | c.1730A>G p.Q577R | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2
- MAPKAP1 | c.1127A>G p.D376G (on ENST00000265960 / NM_001006617.3; = p.D340G on NM_024117.3) | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- NCAM1 | c.2550_2553del p.T851Rfs*10 (on ENST00000316851 / NM_181351.5; = p.T841Rfs*10 on NM_000615.7) | Frame Shift Del (DEL) | VAF 22/196 reads (11%) | called by mutect2, pindel
- OIT3 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.7903G>A p.E2635K | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2
- S1PR4 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.364); called by muse, mutect2
- SETBP1 | c.638A>T p.K213I | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- SLC8A1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.021); called by muse, mutect2
- TEX15 | c.2240C>G p.S747C (on ENST00000256246; = p.S1130C on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2
- TMEM179 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 5/89 reads (6%) | PolyPhen benign (0); called by muse, mutect2
- TRGC1 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRMT1 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- TTN | c.72748C>T p.P24250S (on ENST00000591111; = p.P16826S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/280 reads (6%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- VCAN | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VRK1 | c.788A>C p.D263A | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2
- VWA5B1 | c.2124T>G p.I708M | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2
- VWC2 | c.196del p.A66Rfs*28 | Frame Shift Del (DEL) | VAF 18/132 reads (14%) | called by mutect2, pindel, varscan2
- ZFYVE16 | c.956C>A p.S319* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- C16orf78 | c.672G>A p.E224= | Silent (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- CAMSAP1 | c.741C>T p.D247= | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as rs879692925; called by muse, mutect2
- CDK14 | c.600C>T p.I200= (on ENST00000380050 / NM_001287135.2; = p.I182= on NM_012395.3) | Silent (SNP) | VAF 9/190 reads (5%) | catalogued as COSV56028269, COSV56052742; called by muse, mutect2
- CUX2 | c.2409G>A p.V803= | Silent (SNP) | VAF 18/317 reads (6%) | catalogued as rs758742538, COSV55637195; called by muse, mutect2
- ELOVL4 | c.534A>C p.G178= | Silent (SNP) | VAF 13/313 reads (4%) | called by muse, mutect2
- IDE | c.549G>A p.V183= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- KDM5B | c.2712T>C p.L904= | Silent (SNP) | VAF 68/363 reads (19%) | called by muse, mutect2, varscan2
- MTCL1 | c.1998C>T p.L666= (on ENST00000306329 / NM_001378206.1; = p.L306= on NM_015210.4) | Silent (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- MYBL2 | c.387C>G p.L129= | Silent (SNP) | VAF 8/244 reads (3%) | called by muse, mutect2
- PKD1L1 | c.369G>A p.A123= | Silent (SNP) | VAF 36/263 reads (14%) | catalogued as rs148682146; called by muse, mutect2, varscan2
- SYNRG | c.2724C>G p.L908= | Silent (SNP) | VAF 13/360 reads (4%) | catalogued as rs192119774; called by muse, mutect2
- TBC1D17 | c.714G>A p.L238= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as rs1214865548; called by muse, mutect2
- UBQLN2 | c.459C>G p.G153= | Silent (SNP) | VAF 14/339 reads (4%) | called by muse, mutect2
- ZNF830 | c.348G>A p.A116= | Silent (SNP) | VAF 12/280 reads (4%) | catalogued as COSV58490823; called by muse, mutect2
- ATP1A3 | c.*252G>A | 3'UTR (SNP) | VAF 13/152 reads (9%) | catalogued as rs1227177351, COSV57491269; called by muse, mutect2
- CEP126 | c.507-1811C>A | Intron (SNP) | VAF 18/235 reads (8%) | called by muse, mutect2
- CFAP157 | c.*1459G>A | 3'UTR (SNP) | VAF 15/251 reads (6%) | catalogued as rs1236919774; called by muse, mutect2
- CLCN5 | c.17-39098G>A | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- DLG3 | c.2256-42A>G | Intron (SNP) | VAF 49/235 reads (21%) | called by muse, mutect2, varscan2
- RPL26P30 | n.644G>T | RNA (SNP) | VAF 28/434 reads (6%) | called by muse, mutect2
- STMN2 | c.-36G>T | 5'UTR (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
